TCGA case TCGA-3X-AAVA — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe57b639-db7a-460f-adfe-552f1e034e46

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 50 years; Vital status: Dead; Days to death: 445 days (1.2 years).

Diagnoses (3)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,303 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 271 days; Days to treatment end: 277 days; Treatment dose: 2,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Bone, NOS. Age at diagnosis: 50.8 years (18,567 days); Days to diagnosis: 264 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Liver. Age at diagnosis: 50.8 years (18,568 days); Days to diagnosis: 265 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 264 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 264 days.
- Day 265 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 265 days.
- Days to follow up: 445 days (1.2 years); Disease response: With Tumor.
- ECOG performance status: 1.

Molecular and laboratory tests
- CA19-9: 8 U/mL.
- Platelets 214 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Alpha Fetoprotein 5.4 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 10].
- Creatinine 0.5 mg/dL [Blood test normal range lower: 0.4; Blood test normal range upper: 1.1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg.
- Timepoint category: Prior to Diagnosis; Risk factors: Diabetes, NOS / Tobacco, Smoking.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3X-AAVA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-3X-AAVA-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3X-AAVA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3X-AAVA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Segmentectomy, Single.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 445 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 445 days; disease-free interval: event (new tumor event after initially disease-free), 264 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 264 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3X-AAVA-01A-11D-A416-01): tumor purity 0.79, ploidy 1.89, whole-genome doublings 0.
